Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A1KU, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A1KU-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: Gastric & Mixed Tumo
Account #: [REDACTED] Date of Procedure:
[REDACTED] Date of Receipt:
Physician: [REDACTED]
CC: [REDACTED]
Patient: [REDACTED]

....

Specimens Submitted:

- 1: SP: Spleen, left retroperitoneal liposarcoma, left colectomy, left nephrectomy
- 2: SP: Iliac vein tumor
- 3: SP: Deep pelvic sarcoma
- 4: SP: Distal sigmoid
- 5: SP: Tissue from abdomen for discard

DIAGNOSIS:

1. SPLEEN, LEFT COLON, LEFT KIDNEY, LEFT RETROPERITONEAL LIPOSARCOMA, RESECTION:

- HIGH GRADE DEDIFFERENTIATED LIPOSARCOMA.
- THE DEDIFFERENTIATED LIPOSARCOMA PREDOMINATES AND SHOWS A VARIEGATED APPEARANCE, RANGING FROM A HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA-LIKE GROWTH PATTERN TO LOWER GRADE MYXOID COMPONENTS.
- FOCAL AREAS OF NECROSIS ARE PRESENT.
- TUMOR SIZE IS 33 X 20 X 15 CM.
- TUMOR INVOLVES MESENTERY, SUBSEROSEA OF COLON AND RENAL CAPSULE.
- RENAL PARENCHYMA IS FREE OF TUMOR.
- MOST OF TUMOR IS SURROUNDED BY A THIN INTACT MEMBRANE, EXCEPT FOR A SMALL DISRUPTED AREA.
- URETER MARGIN, PROXIMAL AND DISTAL COLONIC MARGINS ARE FREE OF TUMOR
- SPLEEN IS UNREMARKABLE.

2. ' ILIAC VEIN' TUMOR, RESECTION:

- MULTIPLE NODULES OF WELL-DIFFERENTIATED LIPOSARCOMA, INVOLVING SKELETAL MUSCLE.
- THE BIGGEST TUMOR NODULE MEASURES 1.4 CM IN GREATEST DIMENSION
- ONE BENIGN LYMPH NODE (0/1).

3. PELVIC SARCOMA, RESECTION:

- MULTIPLE NODULES OF WELL-DIFFERENTIATED LIPOSARCOMA.
- THE BIGGEST TUMOR NODULE IS 5.0 CM IN GREATEST DIMENSION.

4. DISTAL SIGMOID, RESECTION:

- SEGMENT OF COLON WITH ACUTE SEROSITIS; NEGATIVE FOR MALIGNANCY.
- ONE BENIGN LYMPH NODE (0/1).

** Continued on next page **

ICD-0-3
dedifferentiated liposarcoma
8858/3

Site: retroperitoneum C48.0

2/1/11
ju

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account # [REDACTED]

Accession # [REDACTED]

Physician: [REDACTED]

Service: Gastric & Mixed Tumo

----- Page 2 of 4

5. SOFT TISSUE, ABDOMEN, EXCISION:

-COLONIC WALL WITH ACUTE SEROSITIS; NEGATIVE FOR MALIGNANCY.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh labeled, "spleen, left retroperitoneal liposarcoma, left colectomy, and left nephrectomy", and consists of soft tissue mass with attached left kidney and fragment of colon, separated spleen. The soft tissue mass measures 33 x 20 x 15 cm, covered with thin membrane with focal area of rupture measuring 10.0 x 8.0 cm. Serial sectioning of the mass reveals myxoid (approximately 5%), tan white solid (approximately 10%) and the tan-yellow fleshy (approximately 80%) areas and focal fat necrosis. The attached left kidney measures 10 x 6.0 x 4.0 cm. Bisecting of the kidney shows grossly and remarkable cortex and medulla. The attached colon measures 45 cm in length, 6.0 cm in circumference and 0.2 cm in thickness. The mucosa and serosa of colon are grossly unremarkable. There are multiple separated, well-circumscribed and tan yellow and fleshy nodules in mesentery, measuring 2.0 cm to 10.0 cm in greatest dimension. The necrotic cyst is identified in mesentery, measuring 10.0 x 8.0 cm. The separated spleen measures 10.0 x 6.0 x 1.5 cm, and is grossly unremarkable. Representative sections are submitted for TPS and permanent sections. Photograph is taken.

Summary of sections:

MYC-myxoid area

SOLI-solid area

FLFS-fleshy area

TN-nodule

RUP-ruptured area

SM-surface membrane

BM-margins of colon

BR-representative section of colon

SP-spleen

K-kidney

NEC-necrotic area

UM-ureter margin and blood vessel margin of kidney

2). The specimen is received in formalin, labeled, "iliac vein tumor" and consists of a 9.2 x 4.5 x 3.5 cm portion of brown-tan to yellow-tan, lobulated soft tissue. Sectioning reveals multiple brown-tan, firm nodules representing possible lymph nodes. The lymph nodes are submitted in twelve

** Continued on next page **

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: Gastric & Mixed Tumo

Date of Report: [REDACTED]

Page 3 of 4

cassettes.

Summary of sections:

LN lymph nodes

BLN bisected lymph nodes

3. The specimen is received fresh labeled, "deep pelvic sarcoma", and consists of one fragment tan yellow fibroadipose tissue measuring 10 x 7 x 4 cm. Two well circumscribed adipose nodules are identified, measuring 5 x 4 x 3 cm and 4 x 2 x 2 cm. Both nodules are entirely covered with thin membrane. Series sectioning of the two nodules reveals tan yellow fleshy surface. Surface of the nodules are inked black. Representative sections are submitted.

Summary of sections:

BN- big nodule

SM- small nodule

R- representative section of the specimen

4) The specimen is received fresh, labeled "distal sigmoid". It consists of an unoriented segment of colon that measures 11 cm in length. The specimen has one stapled (4 cm in length) and one unstapled margin (2.7 cm in diameter). The serosal surface is unremarkable. The radial resection margin is inked black and the specimen is opened to reveal an unremarkable mucosa. Serial sections reveal edema in the wall. Pericolic and peri-rectal adipose tissue is thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted.

Summary of sections:

PM - STAPLED margin

DM - UNSTAPLED margin

SS - representative sections

LN - possible lymph nodes

5). The specimen is received in formalin, labeled "tissue from abdomen for discard" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a plastic piece is noted. There are two pink tan soft tissue rings measuring 2.0 x 1.8 x 0.5 and 1.8 x 1.8 x 0.5 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

** Continued on next page **

Dual/Synchronous Primary Not'd		/

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Physician:

Service: Gastric & Mixed Tumo

----- Page 4 of 4

Summary of Sections:

Part 1: SP: Spleen, left retroperitoneal liposarcoma, left colectomy, left nephrectomy

Block	Sect.	Site	PCs
1	BM		1
1	BR		1
3	FLES		3
1	K		1
3	MYXO		3
1	NEC		1
1	RUP		1
1	SM		1
3	SOLI		3
1	SP		1
3	TN		3
1	UM		1

Part 2: SP: Iliac vein tumor

Block	Sect.	Site	PCs
7	BLN		8
5	LN		7

Part 3: SP: Deep pelvic sarcoma

Block	Sect.	Site	PCs
2	BN		2
1	R		1
1	SN		1

Part 4: SP: Distal sigmoid

Block	Sect.	Site	PCs
1	DM		1
1	LN		1
1	pm		1
2	SS		2

Part 5: SP: Tissue from abdomen for discard

Block	Sect.	Site	PCs
4	U		4

** End of Report **

Source: NCI Genomic Data Commons file e8ac163d-19bf-4406-83a3-2c57f5937dd3 (TCGA-DX-A1KU.F7CDE64F-1352-4F0E-9077-E096EFC1116A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).